Surgical pathology report (de-identified scan), TCGA case TCGA-50-5068, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-50-5068-01A (Primary Tumor).

FINAL DIAGNOSIS:Summary Statement

The right lower lobectomy reveals a 6.8 cm, moderately differentiated adenocarcinoma, with micropapillary growth and psammoma bodies. Pathologic stage is T2 N1 MX.

PART 1: LYMPH NODE, "LEVEL 11 LYMPH NODE", BIOPSY -

- A. SOLITARY LYMPH NODE WITH NO EVIDENCE OF MALIGNANCY.
- B. FOCAL PSAMMOMATOUS CALCIFICATIONS IDENTIFIED (see comment).

PART 2: LYMPH NODE, "LEVEL 7 LYMPH NODE", BIOPSY -

- A. SOLITARY LYMPH NODE WITH NO EVIDENCE OF MALIGNANCY.
- B. FOCAL PSAMMOMATOUS CALCIFICATIONS IDENTIFIED.

PART 3: LUNG, RIGHT LOWER LOBE, LOBECTOMY -

- A. MODERATELY DIFFERENTIATED ADENOCARCINOMA OF LUNG DEMONSTRATING MICROPAPILLARY GROWTH AND PSAMMOMA BODIES. DIAMETER 6.8 CM. NO EVIDENCE OF VISCERAL PLEURAL OR ANGIOLYMPHATIC INVASION. MILD HOST LYMPHOCYTIC RESPONSE. PATHOLOGIC STAGE = T2 N1 MX.
- B. THREE OF THIRTEEN (3/13) N1 LYMPH NODES WITH METASTATIC ADENOCARCINOMA.
- C. SMOKER'S BRONCHIOLITIS WITH EMPHYSEMATOUS CHANGE AND SUBPLEURAL SCARRING.

Source: NCI Genomic Data Commons file bb606d91-3baa-4327-93dd-fb9eb3a09af6 (TCGA-50-5068.D8025F22-0B42-4204-BC58-56FC727C71AC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).